Somatic mutation profile of tumor specimen TARGET-10-PASUGC-09A (aliquot TARGET-10-PASUGC-09A-01D) from TARGET case TARGET-10-PASUGC, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.6 years (3,515 days).
Specimen TARGET-10-PASUGC-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f938ae12-281b-4e2e-a266-52a24f9438fe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PASUGC-10A (Blood Derived Normal), aliquot TARGET-10-PASUGC-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c206f9b8-1305-4ab4-9e30-519b52a1c7e8

The open-access MAF lists 30 somatic variants for this specimen: 20 protein-altering or splice-affecting, 6 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 6, Intron 3, Frame Shift Ins 2, Frame Shift Del 1, In Frame Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CRTC3 | c.1328_1329insCTT p.S443_P444insL | In Frame Ins (INS) | VAF 32/84 reads (38%) | catalogued as COSV51597505; called by mutect2, pindel, varscan2
- DNM2 | c.1078G>A p.A360T | Missense Mutation (SNP) | VAF 75/152 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV58960332; called by muse, mutect2, varscan2
- GSN | c.1044G>T p.K348N | Missense Mutation (SNP) | VAF 117/247 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.315); catalogued as COSV57998428; called by muse, mutect2, varscan2
- HMCN2 | c.10981G>A p.G3661S | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1156518659; called by muse, mutect2, varscan2
- HUNK | c.1352G>A p.R451Q | Missense Mutation (SNP) | VAF 40/81 reads (49%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.559); catalogued as rs142391016; called by muse, mutect2, varscan2
- KIF13A | c.1822C>A p.Q608K | Missense Mutation (SNP) | VAF 50/89 reads (56%) | SIFT tolerated (0.16); PolyPhen benign (0.109); catalogued as COSV52454541; called by muse, varscan2
- NOTCH1 | c.4754T>C p.L1585P | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53025649, COSV53029975, COSV53033143; called by muse, mutect2, varscan2
- OPHN1 | c.1624G>A p.A542T | Missense Mutation (SNP) | VAF 50/54 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV62783116; called by muse, mutect2, varscan2
- OR52B4 | c.312C>A p.F104L | Missense Mutation (SNP) | VAF 100/217 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.287); catalogued as COSV68769105; called by muse, mutect2, varscan2
- PTGFR | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs1027584716, COSV66115400; called by muse, mutect2, varscan2
- RRAS2 | c.68G>C p.G23A | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV56329798, COSV56330700, COSV56332575; called by muse, varscan2
- ST6GAL2 | c.1496C>T p.T499M | Missense Mutation (SNP) | VAF 54/108 reads (50%) | PolyPhen possibly damaging (0.599); catalogued as rs776266456, COSV100699515, COSV62415788, COSV62417299; called by muse, mutect2
- USH2A | c.263G>T p.C88F | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56385191; called by muse, mutect2, varscan2
- WT1 | c.1096_1097insGCGACGTATTAAAGTTGGGACTC p.L366Rfs*79 | Frame Shift Ins (INS) | VAF 43/71 reads (61%) | catalogued as COSV60066264; called by mutect2, pindel, varscan2
- ZBED4 | c.2701C>T p.R901W | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.974); catalogued as COSV53466161; called by muse, mutect2, varscan2
- BAG4 | c.1147del p.I383Sfs*15 | Frame Shift Del (DEL) | VAF 36/104 reads (35%) | called by mutect2, pindel, varscan2
- KRBA1 | c.2707C>A p.L903I | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2
- MPP7 | c.1120G>T p.V374F | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by mutect2, varscan2
- TCERG1 | c.3000dup p.Q1001Tfs*5 | Frame Shift Ins (INS) | VAF 13/32 reads (41%) | called by mutect2, pindel, varscan2
- UBE4A | c.2184C>A p.D728E (on ENST00000252108 / NM_001204077.2; = p.D735E on NM_004788.4) | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.808); called by muse, mutect2
- ALX1 | c.528C>T p.V176= | Silent (SNP) | VAF 61/139 reads (44%) | called by muse, mutect2, varscan2
- CDHR5 | c.1536C>T p.P512= (on ENST00000358353 / NM_001171968.2; = p.P518= on NM_021924.5) | Silent (SNP) | VAF 20/44 reads (45%) | catalogued as rs149585862; called by muse, mutect2
- GUCY2C | c.534C>T p.N178= | Silent (SNP) | VAF 134/265 reads (51%) | catalogued as rs762059100, COSV53793850; called by muse, mutect2, varscan2
- IGSF10 | c.3351C>T p.P1117= | Silent (SNP) | VAF 67/143 reads (47%) | catalogued as COSV56792094; called by muse, mutect2, varscan2
- TNS3 | c.3222G>A p.A1074= | Silent (SNP) | VAF 35/76 reads (46%) | catalogued as rs543251547, COSV60787986; called by muse, mutect2, varscan2
- WFS1 | c.642G>A p.A214= | Silent (SNP) | VAF 50/111 reads (45%) | catalogued as rs761245713; ClinVar: likely benign; called by muse, mutect2, varscan2
- APP | c.1687+8734dup | Intron (INS) | VAF 28/62 reads (45%) | catalogued as rs1326718499; called by mutect2, varscan2
- C19orf12 | chr19:29699165 C>T | 3'Flank (SNP) | VAF 49/125 reads (39%) | catalogued as rs756197130; called by muse, mutect2, varscan2
- EPHA6 | c.1114+22059G>A | Intron (SNP) | VAF 61/118 reads (52%) | catalogued as rs1401638573, COSV67587275; called by muse, mutect2, varscan2
- SLC1A5 | c.567-45T>C | Intron (SNP) | VAF 25/60 reads (42%) | called by muse, mutect2, varscan2
